Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8369, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8369-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED] Case ID	Gross Description	Microscopic Description
[REDACTED]	Stomach segment with a plate -- like tumor of 8.5 cm in its largest dimension, invasion into muscularis propria; fatty tissue lymph nodes are enlarged up to 1 cm in their diameter, soft, hyperemic; omentum -- without changes.	Adenocarcinoma of the stomach, G3; with perigastric fat invasion, mucus producton foci, multiple areas of perineural invasion. Fifteen lymph nodes were examined, seven lymph nodes demonstrated metastases. Omentum demonstrates focal fibrosis.

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:		STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Antrum Tumor size: 8.5 x 0 x 0 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Subserosa Lymph nodes: 7/15 positive for metastasis (Greater and lesser omentum 7/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 3]
	ID	Excision Date	Laterality

Source: NCI Genomic Data Commons file b6ede07c-b11f-4a0c-84aa-e974721a43f9 (TCGA-BR-8369.45C33E8A-A576-45C1-B5DF-6530D4524363.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).